Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7YL, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7YL-01A (Primary Tumor).

[page 1 of 4]
Patient

AP Surgical Pathology: Additional Info Acc#

Surg Path

CLINICAL HISTORY:

Right frontal lobe mass. MRI IMPRESSION: Enhancing enlarged brain mass in the right frontal lobe extending across the corpus callosum. The mass is somewhat more heterogeneous in appearance on the current study than on the prior.

GROSS EXAMINATION:

A. "Brain tissue", received fresh for frozen section and placed in formalin on [redacted] at 2 pm is a 0.6 x 0.3 x 0.2 cm tan-red-brown soft tissue fragment representative section submitted for frozen section in AF1 and frozen section remnant is submitted as block A1.

B. "Brain tissue", received fresh and placed in formalin on [redacted] at 3 pm are two tan-brown hemorrhagic soft tissue fragments ranging from 0.8 to 3 cm. Representative sections submitted in blocks B1-B2.

C. "Brain tissue", received fresh and placed in formalin on [redacted] at 4 pm is a 5.7 x 2.2 x 1.2 cm tan-red-brown soft fragment of tissue consistent with brain representative section submitted in blocks C1-C4.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1- high grade glioma

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a mitotically active and hypercellular gemistocytic astrocytoma. There are some microvascular changes. Endothelial proliferation and necrosis are not seen. There are perivascular lymphocytes.

DIAGNOSIS:

A. BRAIN TISSUE (CRANIOTOMY):

ANAPLASTIC GEMISTOCYTIC ASTROCYTOMA (WHO GRADE III).

B. BRAIN TISSUE (CRANIOTOMY):

ANAPLASTIC GEMISTOCYTIC ASTROCYTOMA (WHO GRADE III).

C. BRAIN TISSUE (CRANIOTOMY):

ANAPLASTIC GEMISTOCYTIC ASTROCYTOMA (WHO GRADE III).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [redacted]

ADDENDUM 1:

Please see Image Cytometry Report [redacted] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (86% OF TUMOR CELLS EXHIBIT POLYSOMY)

Handwritten notes:
100-0-3
Pathology, grade III 94011.3
Pathology, gemistocytic 9411/3
Site: Brain, paraventricular NOS 071.0
Pathology, paraventricular NOS 071.1
9/8/5/14

[page 2 of 4]
EGFR - POLYSOMY (90% OF TUMOR CELLS EXHIBIT POLYSOMY)

CHROMOSOME 10 CENTROMERE - INTACT (NO LOSS)

PTEN - INTACT (NO LOSS)

9p21 - INTACT (NO LOSS)

CHROMOSOME 9 CENTROMERE - INTACT (NO LOSS)

2 OF 4 ABNORMAL MARKERS

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF PATIENTS WITH ANAPLASTIC ASTROCYTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH >2 MARKERS (P=0.037) EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 2:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING ANAPLASTIC GEMISTOCYTIC ASTROCYTOMA (WHO GRADE III; [REDACTED] BLOCK B1).

LEUCOCYTE COMMON ANTIGEN (LCA): 20% OF POSITIVE CELLS.

PROLIFERATION INDEX INTERPRETATION: MODERATE PROLIFERATION INDEX (8% OF TUMOR CELLS EXHIBIT STAINING).

MGMT - POSITIVE (30% OF TUMOR CELLS).

EGFR wt - POSITIVE (2+ IN 70% OF TUMOR CELLS).

EGFR vIII - NEGATIVE (0% OF TUMOR CELLS).

S6 - POSITIVE (2+ IN 30% OF TUMOR CELLS).

AKT - POSITIVE (2+ IN 25% OF TUMOR CELLS).

MAPK - POSITIVE (2+ IN 30% OF TUMOR CELLS).

CARBONIC ANHYDRASE IX: (0%) NEGATIVE: NONE OF THE TUMOR CELLS EXHIBIT STAINING FOR CA-IX ANTIBODY AND THERE ARE NO PERINECROTIC REGION TO EVALUATE.

VEGF IMMUNOHISTOCHEMISTRY: POSITIVE (2 x 60% = score 120). Intensity x distribution => 20 is positive.

PDGFR-A IMMUNOHISTOCHEMISTRY: WIDESPREAD REACTIVITY (60%) FOR CYTOPLASMIC AND/OR MEMBRANE REACTIVITY.

PDGFR-B IMMUNOHISTOCHEMISTRY: WIDESPREAD REACTIVITY (60%) FOR CYTOPLASMIC AND/OR MEMBRANE REACTIVITY.

VEGFR2(KDR) IMMUNOHISTOCHEMISTRY: POSITIVE (2 x 40% = score 80). Intensity x distribution => 20 is positive.

Please see Image Cytometry Report for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above

[page 3 of 4]
~~specimen(s) and have rendered the above diagnosis(es).~~

Electronically signed: [REDACTED]

ADDENDUM 3:

MGMT PROMOTER METHYLATION REAL TIME PCR ANALYSIS

Received [REDACTED] from

is a copy of an MGMT Promoter Methylation Assay, obtained at the request of Dr. [REDACTED], on paraffin block [REDACTED]. The complete report from [REDACTED] is on file in the [REDACTED]

Result:

MGMT PROMOTER METHYLATION NOT IDENTIFIED.

Note:

The specimen is considered negative for MGMT promoter methylation when Methylation Index (MI) is less than 4. MI between 4 and 16 is considered as low level methylation and should be interpreted with caution since the significance of low level methylation in gliomas is not well understood. MI greater than 16 is considered as methylated.

Background:

MGMT (O(6)-methylguanine-DNA methyltransferase) is a DNA repair enzyme that is involved in the repair of damage caused by a variety of DNA crosslinking compounds, including alkylating agents. Increased methylation of the MGMT gene promoter region causes diminished or silenced expression of the gene, making cells more sensitive to DNA damage. This relationship has been shown for glioblastomas and alkylating agents such as Temodar(R) (temozolomide). Approximately 40% to 45% of glioblastoma multiforme (GBM) tumors exhibit MGMT gene methylation. Retrospective studies have shown that detection of MGMT promoter methylation in tumor samples is associated with an increased likelihood of a favorable response to temozolomide.

Methodology:

DNA is isolated from formalin-fixed, paraffin-embedded (FFPE) specimen. Molecular analysis of the MGMT gene is performed by methylation-specific PCR. Molecular-based testing is highly accurate but as in any laboratory test, rare diagnostic errors may occur.

Results of this test are for Investigational Purposes Only. The performance characteristic of this assay have been determined by

The result should not be used as a diagnostic procedure without confirmation of the diagnosis by another medically established diagnostic product or procedure.

References:

1. Vlassenbroeck I. et al. Validation of Real-Time Methylation-Specific PCR to Determine O(6)-Methylguanine-DNA Methyltransferase Gene Promoter Methylation in Glioma. J. Molecular Diagnostics 10;4:332-337. 2008
2. Hegi M. et al. MGMT Gene Silencing and Benefit from Temozolomide in Glioblastoma. New England J Medicine 352; 10:997-1003. 2005.
3. Brandes A. et al. MGMT Promoter Methylation Status Can Predict the Incidence and Outcome of Pseudoprogression After Concomitant Radiochemotherapy in Newly Diagnosed Glioblastoma Patients. J. Clinical Oncology 26; 13:2192-2197. 2008.
4. Hau P. et al. MGMT Methylation Status: The Advent of Stratified Therapy in Glioblastoma. Disease Markers 23:97-104. 2007.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED] Printed by:

[page 4 of 4]
Electronically signed: [REDACTED]

ADDENDUM 4:

Please see MOLECULAR DIAGNOSTICS Report, [REDACTED] for complete report.

IDH1 MUTATION TESTING WITH REFLEX TO IDH2

INTERPRETATION: NEGATIVE

IDH1 AND IDH2 MUTATIONS NOT DETECTED

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 5:

EGFR VIII IMMUNOHISTOCHEMISTRY: NEGATIVE

None of the tumor cells exhibit staining for EGFR VIII (Score = 0).

Please see Image Cytometry Report, [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

Performed by: SURGICAL PATHOLOGY

Ordering MD:

Source: NCI Genomic Data Commons file c53eeffd-2281-425d-a7e5-ea359452ab50 (TCGA-E1-A7YL.4965D7EE-815C-40D9-8071-F017FA7DF335.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).